Gene-level copy-number profile of specimen HCM-SANG-0283-C18-85A from HCMI case HCM-SANG-0283-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0283-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 89b7ba44-1ba4-4956-be39-92d1ab47cd0b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0283-C18-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/1b900677-7a6a-4fe6-8513-a22b3e9d7ebe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 399; copy number 2: 1,699; copy number 3: 16,900; copy number 4: 18,096; copy number 5: 6,776; copy number 6: 9,249; copy number 7: 3,455; copy number 8: 1,338; copy number 9: 867; copy number 10: 99; copy number 11: 3; copy number 12: 12; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:9,082,601–9,088,391, 2 genes (within-gene range 0–2): SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 982 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,596,832–118,185,228, 9 genes, copy number 9–12: AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17.
- chr1:248,548,756–248,645,278, 9 genes, copy number 12: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr7:37,032–31,708,455, 547 genes, copy number 9 (broad region; genes not listed).
- chr7:42,661,716–44,369,292, 53 genes, copy number 9–10: LINC01448, TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1, LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2.
- chr7:44,503,773–56,409,210, 190 genes, copy number 9–10 (broad region; genes not listed).
- chr7:56,462,536–62,275,678, 77 genes, copy number 9 (broad region; genes not listed).
- chr9:61,190,003–61,642,494, 10 genes, copy number 10–11: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:64,621,560–64,652,556, 2 genes, copy number 9: AQP7P2, AL445665.1.
- chr9:64,810,865–64,811,429, 1 gene, copy number 9: BNIP3P4.
- chr9:65,189,995–65,193,610, 1 gene, copy number 17: BMS1P12.
- chr13:18,467,172–19,865,048, 57 genes, copy number 10: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr16:7,878,799–8,112,756, 1 gene, copy number 9: AC093515.1.
- chr16:32,289,547–32,380,049, 3 genes, copy number 9: AC133548.2, AC133548.1, ACTR3BP3.
- chr16:32,439,069–32,478,250, 4 genes, copy number 9–11: PABPC1P13, AC138915.3, AC138915.1, ABCD1P3.
- chr20:25,006,230–25,585,531, 18 genes, copy number 9: ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL.

Autosomal genes at a single copy (total copy number 1): 399. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
